Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A50J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A50J-01A (Primary Tumor).

[page 1 of 3]
Gross Description: Specimen B is designated "right oral tongue and floor of mouth, double long stitch anterior, single long superior/medial." The specimen consists of an oriented portion of tongue with a double stitch marking anterior and a medial stitch marking superior. The specimen measures 5.5 cm anterior to posterior, 4.2 cm superior to inferior, and 1.9 cm medial to lateral. A central exophytic irregular mass is identified measuring 4.2 cm anterior to posterior and 3.8 cm superior to inferior. The remaining mucosa is pale tan and slightly edematous. The specimen is inked as follows: superior blue, anterior orange, inferior red, posterior black, and deep green. The mass is 1.9 cm from the superior mucosal margin, 0.4 cm to the anterior mucosal margin, 0.2 cm from the inferior mucosal margin with a superficial are of ulceration less than 0.1 cm from the inferior mucosal margin and 0.3 cm from the posterior mucosal margin. The specimen is serially sectioned revealing gray-white cut surfaces with a maximal tumor depth of 1.2 cm. It is 0.4 cm to the nearest inferior resection margin. Representative sections are submitted. Specimen B is designated "right oral tongue and floor of mouth, double long stitch anterior, single long superior/medial." The specimen consists of an oriented portion of tongue with a double stitch marking anterior and a medial stitch marking superior. The specimen measures 5.5 cm anterior to posterior, 4.2 cm superior to inferior, and 1.9 cm medial to lateral. A central exophytic irregular mass is identified measuring 4.2 cm anterior to posterior and 3.8 cm superior to

1CD-0-3
carcinoma, squamous cell.
keratinizing, NOS
8071/3
Site: tongue, NOS C02.9
h
10/29/12

[page 2 of 3]
inferior. The remaining mucosa is pale tan and slightly edematous. The specimen is inked as follows: superior blue, anterior orange, inferior red, posterior black, and deep green. The mass is 1.9 cm from the superior mucosal margin, 0.4 cm to the anterior mucosal margin, 0.2 cm from the inferior mucosal margin with a superficial area of ulceration less than 0.1 cm from the inferior mucosal margin and 0.3 cm from the posterior mucosal margin. The specimen is serially sectioned revealing gray-white cut surfaces with a maximal tumor depth of 1.2 cm. It is 0.4 cm to the nearest inferior resection margin. Representative sections are submitted.

Microscopic Description: N/A

Diagnosis Details: B. Right oral tongue and floor of mouth (hemiglossectomy and resection):

- Invasive moderately differentiated keratinizing squamous cell carcinoma of the tongue (tumor size 4.2 x 3.8 cm, depth of invasion 0.9 cm).
- Carcinoma invades salivary gland tissue, probably belonging to minor salivary glands.
- Angiolymphatic invasion is identified.
- Perineural invasion is identified.
- Carcinoma extends to within less than 1.0 mm of the inferior specimen margin; however, no carcinoma is identified at the inked margins.

Comments: N/A

Formatted Path Reports: Right oral tongue and floor of mouth (hemiglossectomy and resection):

- Invasive moderately differentiated keratinizing squamous cell carcinoma of the tongue (tumor size 4.2 x 3.8 cm, depth of invasion 0.9cm).

[page 3 of 3]
- Carcinoma invades salivary gland tissue, probably belonging to minor salivary glands.
- Angiolymphatic invasion is identified.
- Perineural invasion is identified.
- Carcinoma extends to within less than 1.0 mm of the inferior specimen margin; however, no carcinoma is identified at the inked margins.

Criteria	W 10/29/12	No
HIF/A Discrepancy		X
Reviewed Initials	KHL	

Source: NCI Genomic Data Commons file e52693c8-0e13-408a-a427-c0c05535268f (TCGA-F7-A50J.1E3E5AA4-3A0D-4108-9CF2-91B57428B1F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).